Somatic mutation profile of tumor specimen TCGA-P5-A72W-01A (aliquot TCGA-P5-A72W-01A-11D-A32B-08) from TCGA case TCGA-P5-A72W, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 35.2 years (12,848 days).
Specimen TCGA-P5-A72W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f0301bb-b64a-44eb-9f95-7e733956d61f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A72W-10A (Blood Derived Normal), aliquot TCGA-P5-A72W-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ea04e55-07fe-4a29-9205-1cb60a979413

The open-access MAF lists 35 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 29, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/39 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 22/25 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANLN | c.2392A>G p.M798V | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs530432252, COSV99732997; called by muse, mutect2, varscan2
- APOE | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99376329; called by muse, mutect2, varscan2
- ARHGAP18 | c.1264G>C p.A422P | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100936526; called by muse, mutect2, varscan2
- ATP10A | c.3274T>C p.F1092L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100791627; called by muse, mutect2, varscan2
- ATRX | c.4769G>A p.C1590Y | Missense Mutation (SNP) | VAF 45/48 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100971608; called by muse, mutect2, varscan2
- DENND4B | c.1702G>A p.G568R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100768949; called by muse, mutect2, varscan2
- DEPDC5 | c.3145G>A p.G1049R (on ENST00000400246; = p.G1118R on NM_014662.5) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV99836823; called by muse, mutect2, varscan2
- DPEP3 | c.1187T>C p.V396A | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.145); catalogued as COSV99262947; called by muse, mutect2, varscan2
- ENTPD1 | c.740A>G p.N247S | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs780312005, COSV100967851; called by muse, mutect2, varscan2
- FAT1 | c.10123A>C p.I3375L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.175); catalogued as COSV101499683; called by muse, mutect2, varscan2
- GLB1L | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs144432913; called by muse, mutect2, varscan2
- HNRNPC | c.212A>T p.D71V | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV100193440; called by muse, mutect2, varscan2
- LRP1 | c.7539T>A p.D2513E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99677682; called by muse, varscan2
- LUZP2 | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV61213134; called by muse, mutect2, varscan2
- OR2T6 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100861661; called by muse, mutect2, varscan2
- OR4P4 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV100111890; called by muse, mutect2, varscan2
- OSBPL10 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.049); catalogued as COSV101159990, COSV67339565; called by muse, mutect2, varscan2
- PHGDH | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as rs587625944, COSV101025237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCB4 | c.2099C>G p.A700G | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV99597199; called by muse, mutect2, varscan2
- PLCZ1 | c.1319T>A p.L440Q | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.878); catalogued as COSV99857129; called by muse, mutect2, varscan2
- PROCR | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99405852; called by muse, mutect2
- RAD50 | c.3469G>A p.G1157R | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV99529826; called by muse, mutect2, varscan2
- RAMP3 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.602); catalogued as COSV99642478; called by muse, mutect2, varscan2
- RNF26 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as COSV100264970, COSV60990533; called by muse, mutect2, varscan2
- TARBP1 | c.3763G>C p.D1255H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV50178285, COSV99241946, COSV99242214; called by muse, mutect2, varscan2
- TTN | c.56012A>C p.E18671A (on ENST00000591111; = p.E11247A on NM_003319.4) | Missense Mutation (SNP) | VAF 37/80 reads (46%) | PolyPhen possibly damaging (0.652); catalogued as COSV100634372; called by muse, mutect2, varscan2
- ZNRD2 | c.362G>C p.R121P | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100326240; called by muse, mutect2
- IGHV3-21 | c.237C>T p.Y79= | Silent (SNP) | VAF 59/122 reads (48%) | catalogued as rs368900048; called by muse, mutect2, varscan2
- KCNJ3 | c.489C>G p.L163= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV54533276, COSV99716615; called by muse, mutect2, varscan2
- KLHL38 | c.870C>T p.G290= | Silent (SNP) | VAF 84/129 reads (65%) | catalogued as rs369848638; called by muse, mutect2, varscan2
- SLC43A3 | c.54G>A p.L18= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV100725278; called by muse, mutect2, varscan2
- TRAV7 | c.6G>A p.E2= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- ZNF831 | c.2442G>A p.G814= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs368710582, COSV64038818; called by mutect2, varscan2
